Surgical pathology report (de-identified scan), TCGA case TCGA-44-2655, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-2655-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN

- A. Posterior segment right
- B. Node level 10
- C. Level 11
- D. Right upper lobe
- E. 2R fat pad
- F. 4R node
- G. Level 7

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung lesion

FROZEN SECTION DIAGNOSIS

A - Adenocarcinoma

GROSS DESCRIPTION

A. Received fresh for frozen section labeled "posterior segment right" and consists of a peripheral wedge resection of lung measuring 9.5 x 3 x 2.3 cm. There is a staple line which runs longitudinally. On the opposite surface there is a stitch denoting the location of a lesion. The total surface is smooth and glistening. On sectioning the area of the stitch, there is a subpleural ill defined area of induration measuring 1.5 x 1 x 1 cm. A touch preparation and frozen section are performed. Samples of this nodule as well as samples of normal lung tissue are taken for tissue procurement. The staple line is removed. The margin is painted black. The remaining parenchyma is soft pink and spongy. Additional sections are submitted in six blocks, following fixation.

B. Received fresh, subsequently fixed in formalin labeled "node level 10" is a 0.5 cm black-red irregular soft tissue fragment which is entirely submitted in one cassette. AS-1. mkw:km

C. Received fresh, subsequently fixed in formalin labeled "level 11" are two black red irregular soft tissue

[page 2 of 4]
SPECIMEN

- A. Posterior segment right
- B. Node level 10
- C. Level 11
- D. Right upper lobe
- E. 2R fat pad
- F. 4R node
- G. Level 7

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung lesion

FROZEN SECTION DIAGNOSIS

A - Adenocarcinoma

GROSS DESCRIPTION

A. Received fresh for frozen section labeled "posterior segment right" and consists of a peripheral wedge resection of lung measuring 9.5 x 3 x 2.3 cm. There is a staple line which runs longitudinally. On the opposite surface there is a stitch denoting the location of a lesion. The total surface is smooth and glistening. On sectioning the area of the stitch, there is a subpleural ill defined area of induration measuring 1.5 x 1 x 1 cm. A touch preparation and frozen section are performed. Samples of this nodule as well as samples of normal lung tissue are taken for tissue procurement. The staple line is removed. The margin is painted black. The remaining parenchyma is soft pink and spongy. Additional sections are submitted in six blocks, following fixation.

B. Received fresh, subsequently fixed in formalin labeled "node level 10" is a 0.5 cm black-red irregular soft tissue

fragment which is entirely submitted in one cassette. AS-1.

C. Received fresh, subsequently fixed in formalin labeled "level 11" are two black red irregular soft tissue

[page 3 of 4]
GROSS DESCRIPTION

fragments which are 0.4 cm and 0.2 cm in greatest dimension.

Specimens are entirely submitted in one cassette. AS-1.

D. Received fresh subsequently fixed and inflated with formalin labeled "right upper lobe" is an 11.5 x 9.8 x 5.3 cm portion of lung which shows two staple lines measuring 11.5 and 8.5 cm. Both staple lines are located near the hilar surface. The hilum of the specimen shows few possible lymph nodes present. Multiple staples are grossly identified. The staples are removed and staple lines are inked blue. The pleura of the specimen is violaceous smooth glistening and shows no umbilication or puckering present. The cut surface of the specimen is red-brown and spongy. No discrete gross lesions are identified or are palpated. Representative sections of the specimen are submitted as follows: Block 1 - possible hilar nodes; block 2 - bronchial and vascular margins; block 3-8 - representative sections of the specimen. RS-8.

E. Received in formalin labeled "2R fat pad" are two yellow black irregular soft tissue fragments which average 2.0 x 1.2 x 0.3 cm. The specimens are entirely submitted in one cassette. AS-1.

F. Received fresh subsequently fixed in formalin labeled "4R node" is a 1.5 x 0.7 x 0.5 cm pink-red irregular rubbery tissue fragment which is bisected and entirely submitted in one cassette. AS-1.

G. Received fresh, subsequently fixed in formalin labeled "level 7" is a 1.5 x 0.7 x 0.5 cm black irregular soft rubbery tissue fragment which is bisected and entirely submitted in one cassette. AS-1.

MICROSCOPIC DESCRIPTION

A. This wedge resection contains a subpleural tumor mass.

The touch preparation discloses moderately differentiated adenocarcinoma. Histologic sections disclose and infiltrating moderately differentiated adenocarcinoma with a peripheral bronchoalveolar type growth pattern. The tumor is strongly positive for TTF1, supporting a lung primary. The tumor measures 1.5 cm in gross maximum dimension. Please see the template below.

Histologic type: Infiltrating adenocarcinoma

Histologic grade: Moderately differentiated

Primary tumor (pT): The tumor measures 1.5 cm,

Margins of resection: Negative

Direct extension of tumor: Negative

Venous (large vessel) invasion: Negative

Arterial (large vessel) invasion: Negative

Lymphatic (small vessel) invasion: Negative

Regional lymph nodes (pN): As per part B through G, at least 11 lymph nodes are present, all negative for metastatic disease, pN0

[page 4 of 4]
Distant metastasis (pM): Cannot be assessed
Other findings: Mild emphysematous change is noted.

B&C. Microscopic examination performed.

D. This right upper lobe is status post prior wedge resection. The remaining lobe is negative for tumor. Bronchial and vascular margins of resection are negative for tumor. A single subpleural focus of nonspecific scarring (block #7) is noted, measuring 2 cm in maximum dimension. The lung parenchyma discloses mild to moderate emphysematous change. Five hilar lymph nodes are found with anthracosis, all negative for metastatic disease.

E-G. Microscopic examination performed.

MICROSCOPIC DESCRIPTION

[A few of the antibodies used in our laboratory may be classified as analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

14, 65, 5, 4x3, 3x3, 20

DIAGNOSIS

- A. Posterior segment of right lung, wedge resection -- Peripheral portion of lung with infiltrating moderately differentiated adenocarcinoma of lung. The pleura and margin of resection are negative for tumor. No vascular invasion is found.
- B. Level 10 lymph node, biopsy -- Single lymph node with anthracosis, negative for metastatic disease, 0/1.
- C. Level 11 lymph node, biopsy -- Crushed fibrous and lymphoid tissue negative for tumor.
- D. Right upper lobe, right upper lobectomy -- Right upper lobe, status post prior wedge resection, negative for residual tumor. All five regional lymph nodes are negative for metastatic disease, 0/5.
Nonspecific focus of subpleural scar present and emphysematous change is noted.
- E. 2R fat pad, excision -- Single lymph node negative for metastatic disease, 0/1.
- F. 4R node, dissection -- Two lymph nodes negative for metastatic disease, 0/2.
- G. Level 7 lymph nodes, dissection -- Two lymph nodes negative for metastatic disease, 0/2.
-

Source: NCI Genomic Data Commons file f7baac20-0956-41fe-a9ca-4eeb9d223bf4 (TCGA-44-2655.EBAE1E0E-18FB-48C8-B2F3-282DAB7352D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).